Somatic mutation profile of tumor specimen TCGA-EM-A2CK-01A (aliquot TCGA-EM-A2CK-01A-11D-A17V-08) from TCGA case TCGA-EM-A2CK, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 28.7 years (10,485 days).
Specimen TCGA-EM-A2CK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8aba6c33-f360-419b-b78e-453a4578d36e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2CK-10A (Blood Derived Normal), aliquot TCGA-EM-A2CK-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/363cf6e4-4714-4f17-94c6-746fcaf658e8

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 57/134 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHST8 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52858186, COSV52863186; called by muse, mutect2, varscan2
- FHL3 | c.427C>G p.P143A | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65952472, COSV65952852; called by muse, mutect2, varscan2
- LRFN3 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 92/277 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs1203149145, COSV55818257; called by muse, mutect2, varscan2
- LRRC8A | c.1550C>T p.T517I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV52189295; called by muse, mutect2, varscan2
- PCM1 | c.3758T>G p.F1253C | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59588786; called by muse, mutect2
- MOG | c.*252C>G | 3'UTR (SNP) | VAF 43/117 reads (37%) | catalogued as COSV65307015; called by muse, mutect2, varscan2
